Somatic mutation profile of tumor specimen MMRF_2480_1_BM_CD138pos (aliquot MMRF_2480_1_BM_CD138pos_T1_KHS5U_L11605) from MMRF case MMRF_2480, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.9 years (23,329 days).
Specimen MMRF_2480_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a8831ea-4aae-4884-b6ae-1085ecd9eedd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2480_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2480_1_PB_Whole_C3_KHS5U_L11606; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5fcc8ea-8482-4177-af94-e6c2d9d209c3

The open-access MAF lists 94 somatic variants for this specimen: 35 protein-altering or splice-affecting, 9 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 32, Missense Mutation 31, Silent 9, Intron 6, RNA 5, 3'Flank 3, 5'UTR 2, 5'Flank 2, In Frame Del 1, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 45/325 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- ARSK | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs370552188, COSV66170067; called by muse, mutect2, varscan2
- BTBD2 | c.824T>C p.L275P | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1448331455, COSV99724573; called by muse, mutect2, varscan2
- C16orf78 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs373637026, COSV54558555; called by muse, mutect2, varscan2
- HECW2 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV99646892; called by muse, mutect2, varscan2
- IGHJ6 | c.50C>G p.T17S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | PolyPhen probably damaging (0.948); catalogued as rs782547286; called by muse, varscan2
- IGHV4-34 | c.181A>G p.S61G | Missense Mutation (SNP) | VAF 142/274 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs767692723; called by muse, varscan2
- IGHV4-34 | c.87G>C p.Q29H | Missense Mutation (SNP) | VAF 106/203 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as rs11267027; called by muse, mutect2, varscan2
- NECTIN2 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs1479176655; called by muse, mutect2
- RNF34 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 44/312 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs61754471, COSV63443086; called by muse, mutect2, varscan2
- SLC5A11 | c.805C>T p.L269F | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.286); catalogued as rs964526073; called by muse, mutect2, varscan2
- ZNF654 | c.3164A>C p.Y1055S | Missense Mutation (SNP) | VAF 85/378 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58806790; called by muse, mutect2, varscan2
- ACAP1 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- CAPN14 | c.1828C>A p.Q610K | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- CCDC74B | c.914G>A p.R305K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.042); called by muse, varscan2
- CPT1C | c.2242G>A p.G748R | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.775); called by muse, mutect2
- CSMD1 | c.9794G>A p.S3265N (on ENST00000520002; = p.S3264N on NM_033225.6) | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GALR1 | c.925A>T p.N309Y | Missense Mutation (SNP) | VAF 71/414 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IGHV1-69D | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 168/344 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- IGHV4-34 | c.86A>C p.Q29P | Missense Mutation (SNP) | VAF 107/205 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- INPP4B | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- METTL16 | c.1480G>T p.E494* | Nonsense Mutation (SNP) | VAF 16/516 reads (3%) | called by muse, mutect2
- MON2 | c.278T>G p.L93R | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- MTFR2 | c.121A>C p.I41L | Missense Mutation (SNP) | VAF 29/234 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- OR52B6 | c.866dup p.C290Mfs*28 | Frame Shift Ins (INS) | VAF 34/214 reads (16%) | called by mutect2, pindel, varscan2
- PDE7A | c.1407G>C p.E469D (on ENST00000401827 / NM_001242318.3; = p.E443D on NM_002603.4) | Missense Mutation (SNP) | VAF 20/478 reads (4%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, mutect2
- SGPP1 | c.542T>A p.I181N | Missense Mutation (SNP) | VAF 147/378 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, varscan2
- SGPP1 | c.450C>G p.F150L | Missense Mutation (SNP) | VAF 140/348 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, varscan2
- SUPT5H | c.1900G>A p.G634S | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUSD5 | c.1073C>A p.A358E | Missense Mutation (SNP) | VAF 83/392 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- THADA | c.3423_3428del p.S1141_L1143delinsR | In Frame Del (DEL) | VAF 37/261 reads (14%) | called by mutect2, pindel, varscan2
- TRIM27 | c.384C>A p.S128R | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by mutect2, varscan2
- TRIM27 | c.372_382del p.H124Qfs*43 | Frame Shift Del (DEL) | VAF 33/146 reads (23%) | called by mutect2, pindel, varscan2
- UCHL5 | c.436C>A p.Q146K | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.095); called by mutect2, varscan2
- WDR64 | c.248A>G p.N83S | Missense Mutation (SNP) | VAF 22/513 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2
- ABTB2 | c.2088G>A p.A696= | Silent (SNP) | VAF 32/248 reads (13%) | catalogued as rs761722461; called by muse, mutect2, varscan2
- BBOX1 | c.705T>C p.F235= | Silent (SNP) | VAF 55/118 reads (47%) | called by muse, mutect2, varscan2
- CSMD1 | c.5190G>T p.V1730= (on ENST00000520002; = p.V1729= on NM_033225.6) | Silent (SNP) | VAF 50/104 reads (48%) | called by muse, varscan2
- FAT1 | c.5193C>A p.P1731= | Silent (SNP) | VAF 111/273 reads (41%) | called by muse, mutect2, varscan2
- HIC2 | c.696C>T p.S232= | Silent (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- MGLL | c.528C>T p.L176= (on ENST00000398104 / NM_001003794.2; = p.L186= on NM_007283.6) | Silent (SNP) | VAF 73/162 reads (45%) | catalogued as rs768453662, COSV54027404; called by muse, mutect2, varscan2
- STK36 | c.2979G>A p.A993= | Silent (SNP) | VAF 55/224 reads (25%) | catalogued as rs781197058, COSV99831304; called by muse, mutect2, varscan2
- TENT5C | c.1122C>T p.A374= | Silent (SNP) | VAF 28/212 reads (13%) | called by muse, mutect2, varscan2
- ZNF430 | c.822A>T p.S274= | Silent (SNP) | VAF 82/150 reads (55%) | called by muse, mutect2, varscan2
- AC007064.4 | n.51A>T | RNA (SNP) | VAF 29/184 reads (16%) | called by muse, mutect2, varscan2
- AC021218.1 | n.1491T>A | RNA (SNP) | VAF 13/228 reads (6%) | called by muse, mutect2
- AC084082.1 | n.324C>T | RNA (SNP) | VAF 47/397 reads (12%) | called by muse, mutect2, varscan2
- B3GALNT1 | c.*1303A>T | 3'UTR (SNP) | VAF 13/122 reads (11%) | called by muse, mutect2
- CAB39L | c.*279C>T | 3'UTR (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- CCDC125 | c.*1936A>G | 3'UTR (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- CLVS2 | c.*75G>A | 3'UTR (SNP) | VAF 18/388 reads (5%) | catalogued as COSV99252165; called by muse, mutect2
- CMPK1 | c.*233A>T | 3'UTR (SNP) | VAF 31/54 reads (57%) | called by muse, mutect2, varscan2
- COL27A1 | c.*593C>T | 3'UTR (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- COX10 | c.*834T>A | 3'UTR (SNP) | VAF 16/117 reads (14%) | called by mutect2, varscan2
- CPLX4 | c.*1175G>A | 3'UTR (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2, varscan2
- CTBS | c.*1172A>T | 3'UTR (SNP) | VAF 29/84 reads (35%) | called by muse, mutect2, varscan2
- EPHA5 | c.*4173T>A | 3'UTR (SNP) | VAF 73/167 reads (44%) | called by muse, mutect2, varscan2
- FLRT2 | c.-145T>A | 5'UTR (SNP) | VAF 59/94 reads (63%) | called by muse, mutect2, varscan2
- FOXRED1 | c.733+38A>G | Intron (SNP) | VAF 45/128 reads (35%) | called by muse, mutect2, varscan2
- GTF2F1 | chr19:6396415 C>A | 5'Flank (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- GULP1 | c.843+2596G>T | Intron (SNP) | VAF 67/167 reads (40%) | catalogued as rs1159993771; called by muse, mutect2, varscan2
- H3-3B | chr17:75784575 G>A | 5'Flank (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- KRAS | c.*129T>C | 3'UTR (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- KRAS | c.*20T>C | 3'UTR (SNP) | VAF 20/122 reads (16%) | catalogued as CM070969, COSV56141427; called by muse, varscan2
- LINC01460 | n.2552C>T | RNA (SNP) | VAF 30/166 reads (18%) | catalogued as rs142472237; called by muse, mutect2, varscan2
- MBL2 | c.*264T>C | 3'UTR (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- NAALADL2 | c.*910dup | 3'UTR (INS) | VAF 19/123 reads (15%) | called by mutect2, pindel, varscan2
- NBPF22P | n.1484G>T | RNA (SNP) | VAF 45/247 reads (18%) | called by muse, mutect2, varscan2
- NKAIN4 | c.*688G>A | 3'UTR (SNP) | VAF 27/135 reads (20%) | called by mutect2, varscan2
- NRCAM | c.*906G>T | 3'UTR (SNP) | VAF 26/121 reads (21%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.*5651G>T | 3'UTR (SNP) | VAF 27/173 reads (16%) | called by muse, mutect2, varscan2
- PPP2R2C | c.71-1370T>G | Intron (SNP) | VAF 9/175 reads (5%) | called by muse, mutect2
- PRKAA2 | c.*2893T>A | 3'UTR (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- PTCD3 | c.*2395A>G | 3'UTR (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- RC3H1 | c.*4545G>T | 3'UTR (SNP) | VAF 24/107 reads (22%) | called by muse, mutect2, varscan2
- REV1 | c.2614+17G>A | Intron (SNP) | VAF 83/181 reads (46%) | called by muse, mutect2, varscan2
- RNASEK | c.-120C>T | 5'UTR (SNP) | VAF 11/224 reads (5%) | called by muse, mutect2
- RRP15 | c.*6553T>A | 3'UTR (SNP) | VAF 34/150 reads (23%) | called by muse, varscan2
- SENP1 | c.*1098G>A | 3'UTR (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- SERPINB1 | c.*290C>T | 3'UTR (SNP) | VAF 19/123 reads (15%) | called by muse, mutect2, varscan2
- SH3BGRL2 | c.*476G>T | 3'UTR (SNP) | VAF 22/93 reads (24%) | called by muse, mutect2, varscan2
- SNAPC3 | c.*3515C>A | 3'UTR (SNP) | VAF 9/67 reads (13%) | catalogued as rs1029660358; called by muse, mutect2, varscan2
- SOX5 | c.*3959T>A | 3'UTR (SNP) | VAF 4/84 reads (5%) | called by muse, mutect2
- STC2 | c.*2032G>A | 3'UTR (SNP) | VAF 14/216 reads (6%) | called by muse, mutect2
- SYT14 | chr1:210163492 T>C | 3'Flank (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- TACC3 | c.2452-32del | Intron (DEL) | VAF 14/162 reads (9%) | called by mutect2, pindel
- THOP1 | c.751-56C>A | Intron (SNP) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- TXLNA | c.*866G>A | 3'UTR (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- UBE2H | c.*475G>A | 3'UTR (SNP) | VAF 18/90 reads (20%) | catalogued as rs537175593; called by muse, mutect2, varscan2
- UNC13B | c.*733G>A | 3'UTR (SNP) | VAF 15/240 reads (6%) | called by muse, mutect2
- WHAMMP3 | chr15:22690809 C>T | 3'Flank (SNP) | VAF 73/156 reads (47%) | catalogued as rs1340582520; called by muse, mutect2
- WRNIP1 | c.*343T>C | 3'UTR (SNP) | VAF 28/60 reads (47%) | catalogued as rs942646837; called by muse, mutect2, varscan2
- WWP1 | chr8:86468226 A>G | 3'Flank (SNP) | VAF 31/56 reads (55%) | called by muse, mutect2, varscan2
- ZNF33A | c.*2815A>C | 3'UTR (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
